Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A3KF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A3KF-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, capsule at lesser curve of stomach, excision
- Dense fibrous tissue with chronic inflammation and necrotic debris with
numerous hemosiderin laden macrophages
- Negative for malignancy

B: Liver, segments 2 and 3, left hepatic resection

Histologic tumor type/subtype: hepatocellular carcinoma (see comment)

Histologic grade: grade 3 of 4 (Edmondson and Steiner classification)

Tumor location: segments 2 and 3

Tumor size: 10 cm

ICD-0-3
carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 W 12/19/11

Focality/extent: unifocal

Tumor necrosis/treatment effect: present; tumor appears approximately 75% viable

Vascular invasion: present

Perineural invasion: not identified

Capsular invasion: not identified

Margins: negative for malignancy; tumor is 4 mm from the cranial hepatic margin and 4 mm from the caudal hepatic margin

Background liver: mild macrovesicular steatosis involving approximately 20% of hepatic parenchyma

AJCC PATHOLOGIC TNM STAGE: pT2 pNx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and

[page 2 of 3]
additional information.

Comment:

Immunohistochemical stains are performed and demonstrate the tumor is diffusely positive for HepPar-1 while being negative for CK7 and CK20. Vimentin and CD31 outline blood vessels. Overall the immunohistologic and immunohistochemical features are consistent with hepatocellular carcinoma.

Intraoperative Consult Diagnosis:

A frozen section was requested by Dr. on . . . at . . . from . . .

FSA1: Liver, capsule at lesser curve of stomach, biopsy
- Chronic inflammation and fibrosis

Drs. at . . . am on . . .

Frozen Section Pathologist:, MD

Clinical History:

The patient is a . . .-year-old female with a clinical diagnosis of hepatocellular carcinoma. Operation being performed is "left hepatic resection". As per Web Cis, the patient has a 9.2 x 8.9 mass involving segments 2 and 3 in the left lobe of the liver.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "liver capsule at lesser curve of stomach" and holds one tan cassette and bits of soft tissue. The cassette is additionally labeled "MS11- FSA1". At frozen section specimen A is described as weighing 1.7 grams and measuring 3.4 x 1.7 x 0.5 cm and appears as a red/tan soft tissue fragment that was serially sectioned. A representative

[page 3 of 3]
section was submitted into block FSA1. On gross examination the remaining strips of soft tissue are submitted into blocks A1 and A2 with no tissue remaining.

Container B is additionally labeled "hepatocellular carcinoma, segments 2 and 3 of liver, long stitch = cranial hepatic margin at IVC, short stitch = caudal hepatic margin".

Specimen Type: Left hepatic resection, segments 2 and 3

Specimen Weight: 480 grams

Measurement: 12.4 x 10.7 x 8.7 cm

Orientation: The margin of resection has been previously inked as

follows: long stitch half/black (cranial), short stitch half/blue (caudal).

Mass: The cut section of the liver parenchyma shows a 10 x 7.9 x 7.5 cm yellow/tan mass; focal areas of hemorrhage and necrosis are evidence,

with an estimate percent necrosis at 30%

Adjacent liver tissue: Tan with no other masses or lesions identified.

Capsule: Shows focal fibrofatty adhesions with an area of the liver mass. The remaining portion of the capsule is smooth.

Major portal vein/ hepatic vein: N/A

Margins: At closest approach, the liver mass is 0.3 cm away from the margin of resection.

Gallbladder: Not present

Block Summary:

Inking: Cranial margin/black, caudal margin/blue

B1-B2 - Tumor and margin of resection

B3 -

B4-B9 - Tumor, representative sections

B10 - Liver and normal liver, transition

B11 - Normal liver

Source: NCI Genomic Data Commons file 8cd8ccf3-4355-403c-8f23-41a5a3fae6e9 (TCGA-BC-A3KF.AFBED89A-FA3F-45E9-9824-AEE5F891C5B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).